MMRF case MMRF_2455 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/684e30cb-0db5-4624-aa80-a99816e6a787

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Dead; Days to death: 264 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.1 years (23,048 days); ISS stage: II; Days to last known disease status: 264 days; Days to last follow up: 264 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 257 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 255 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 264.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -17 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 119 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 800 mg/dL; Immunoglobulin G 3.89 g/L; Immunoglobulin A 34.2 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 5.2 µg/mL; Lactate Dehydrogenase 4.05 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 5.54 ×10⁹/L; Absolute Neutrophil 3.69 ×10⁹/L; Platelets 257 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.48 mmol/L; Albumin 32 g/L; Total Protein 9.7 g/dL; Glucose 6.11 mmol/L.
- Day 65 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 187 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 92 mg/dL; Immunoglobulin G 7.18 g/L; Immunoglobulin A 1.53 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 1.7 µg/mL; Hemoglobin 8.06 mmol/L; Leukocytes 7.73 ×10⁹/L; Absolute Neutrophil 7.07 ×10⁹/L; Platelets 333 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.2 g/dL; Glucose 7.1 mmol/L.
- Day 163 (ECOG 1): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 168 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 265 mg/dL; Immunoglobulin G 6.01 g/L; Immunoglobulin A 9.23 g/L; Immunoglobulin M 0.05 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 5.74 ×10⁹/L; Absolute Neutrophil 3.44 ×10⁹/L; Platelets 309 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.05 mmol/L; Albumin 35 g/L; Total Protein 6.5 g/dL; Glucose 5.34 mmol/L.
- Day 255 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 201 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 384 mg/dL; Immunoglobulin G 7.22 g/L; Immunoglobulin A 12.6 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 0.3 µg/mL; Hemoglobin 5.46 mmol/L; Leukocytes 4.95 ×10⁹/L; Absolute Neutrophil 3.01 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 177 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 1.75 mmol/L; Albumin 15 g/L; Total Protein 6.9 g/dL; Glucose 6.55 mmol/L.

Other clinical attributes
- Day -17: Weight: 82 kg; Height: 175 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2455_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -17 days.
- Sample MMRF_2455_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -17 days.
